TARGET case TARGET-20-ECandCBtransferexp-ECplusTAH002-TAH002CBFcells — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/4148f096-4ad9-49c8-9e0a-d9cd0a6a5a7a

Biospecimens (1 sample)
- Sample TARGET-20-ECandCBtransferexp-ECplusTAH002-TAH002CBFcells-85: Sample type: Next Generation Cancer Model; Tissue type: Tumor.
